RC case RC-B65N — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/89300f51-3205-4bd0-a899-d1bd5532483f

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1945; Vital status: Alive.

Diagnoses (3)
1. T-cell large granular lymphocytic leukemia (the primary disease): ICD-O-3 morphology code: 9831/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 69.1 years (25,246 days); Year of diagnosis: 2014; Method of diagnosis: Core Biopsy; Ann Arbor B symptoms: No; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Recorded as not given: Organ Transplantation; adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, NOS.
2. Prior malignancy of the skin (histology not recorded by GDC). Age at diagnosis: 37.7 years (13,768 days); Year of diagnosis: 1983; Days to diagnosis: -11,478 days (-31.4 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -11,478 days (-31.4 years); Treatment anatomic sites: Other.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Prior malignancy of the skin (histology not recorded by GDC). Age at diagnosis: 67.7 years (24,726 days); Year of diagnosis: 2013; Days to diagnosis: -520 days (-1.4 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -520 days (-1.4 years); Treatment anatomic sites: Other.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100.
- Day 1,638 (end of treatment course 1): Disease response: With Tumor.

Molecular and laboratory tests
- Lactate Dehydrogenase 185 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Celiac Disease / Hypotension / Osteoporosis or Osteopenia / Barrett's Esophagus / Lyme Disease.
- Timepoint category: Initial Diagnosis; Weight: 67.7 kg; Height: 167.5 cm; BMI: 24.1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample RC-B65N-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B65N-TBP1-B: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
